Somatic mutation profile of tumor specimen C3L-06113-01 (aliquot CPT0319820006) from CPTAC case C3L-06113, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 62.7 years (22,890 days).
Specimen C3L-06113-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Chest; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) db495b23-c1ab-45e2-92f9-75ad17f129a4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-06113-31 (Blood Derived Normal), aliquot CPT0319880002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a32f01f9-b53b-4c42-93d8-b5c368ad3f7e

The open-access MAF lists 160 somatic variants for this specimen: 102 protein-altering or splice-affecting, 52 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 94, Silent 52, Nonsense Mutation 4, 5'UTR 3, Frame Shift Del 2, Splice Region 1, Splice Site 1, 3'UTR 1, 5'Flank 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 124/293 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- SLC26A4 | c.416-1G>A p.X139_splice | Splice Site (SNP) | VAF 78/188 reads (41%) | catalogued as rs1057516988, CS080739, COSV99706912; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AKR1B15 | c.519G>A p.M173I | Missense Mutation (SNP) | VAF 125/339 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.44); catalogued as rs866171696; called by muse, mutect2, varscan2
- ALKBH6 | c.203G>A p.R68Q (on ENST00000252984 / NM_001297701.2; = p.R96Q on NM_032878.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 71/301 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.434); catalogued as rs1274474050, COSV99431054, COSV99431236; called by muse, mutect2, varscan2
- ARHGAP24 | c.265C>T p.P89S | Missense Mutation (SNP) | VAF 34/182 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.023); catalogued as rs761058241; called by muse, mutect2, varscan2
- ASH1L | c.7990C>T p.R2664C (on ENST00000368346 / NM_001366177.2; = p.R2659C on NM_018489.3) | Missense Mutation (SNP) | VAF 83/269 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as rs369466292; called by muse, mutect2, varscan2
- ATP13A1 | c.2323C>T p.P775S | Missense Mutation (SNP) | VAF 82/286 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.021); catalogued as rs1166872929; called by muse, mutect2, varscan2
- ATP8A2 | c.1783G>A p.D595N | Missense Mutation (SNP) | VAF 46/183 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs771286370; called by muse, mutect2, varscan2
- C17orf107 | c.433C>T p.R145W | Missense Mutation (SNP) | VAF 154/514 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.799); catalogued as rs533993446; called by muse, mutect2, varscan2
- CCDC168 | c.2174C>T p.S725F | Missense Mutation (SNP) | VAF 55/264 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.169); catalogued as COSV70556166; called by muse, mutect2, varscan2
- CD207 | c.905C>T p.S302L | Missense Mutation (SNP) | VAF 57/341 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.028); catalogued as COSV69652837; called by muse, mutect2, varscan2
- CHIT1 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 94/347 reads (27%) | SIFT tolerated (0.89); PolyPhen benign (0.041); catalogued as COSV55145321; called by muse, mutect2, varscan2
- CHMP4C | c.305A>G p.N102S | Missense Mutation (SNP) | VAF 135/393 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); catalogued as rs754281858; called by muse, mutect2, varscan2
- CLCN1 | c.2615G>A p.G872E | Missense Mutation (SNP) | VAF 77/382 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58367372; called by muse, mutect2, varscan2
- CLSTN2 | c.2622G>A p.M874I | Missense Mutation (SNP) | VAF 106/414 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.039); catalogued as rs1455949489; called by muse, mutect2, varscan2
- DCC | c.2065G>A p.G689R | Missense Mutation (SNP) | VAF 53/232 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV100498966; called by muse, mutect2, varscan2
- DCHS2 | c.298G>T p.G100C | Missense Mutation (SNP) | VAF 138/437 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59718833; called by mutect2, varscan2
- DCST1 | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 102/402 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); catalogued as rs372006655; called by muse, mutect2, varscan2
- DDX41 | c.931C>T p.R311* | Nonsense Mutation (SNP) | VAF 47/251 reads (19%) | catalogued as rs899399494, COSV57252072; called by muse, mutect2, varscan2
- DOK5 | c.640C>T p.R214* | Nonsense Mutation (SNP) | VAF 82/324 reads (25%) | catalogued as rs746485155; called by muse, mutect2, varscan2
- DSCAM | c.2732G>A p.G911E | Missense Mutation (SNP) | VAF 35/258 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV68037429; called by muse, mutect2, varscan2
- EML4 | c.437C>T p.S146F | Missense Mutation (SNP) | VAF 93/283 reads (33%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.656); catalogued as rs763563612; called by muse, mutect2, varscan2
- ETV5 | c.1174C>T p.R392* | Nonsense Mutation (SNP) | VAF 78/325 reads (24%) | catalogued as COSV100112642; called by muse, mutect2, varscan2
- HIF3A | c.1705C>T p.R569W (on ENST00000377670 / NM_152795.4; = p.R500W on NM_022462.4) | Missense Mutation (SNP) | VAF 72/245 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.867); catalogued as rs140829009, COSV52198849; called by muse, mutect2, varscan2
- HOOK1 | c.1973G>A p.R658H | Missense Mutation (SNP) | VAF 48/201 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.274); catalogued as rs749441451, COSV64617692; called by muse, mutect2, varscan2
- IL36B | c.32C>T p.S11F | Missense Mutation (SNP) | VAF 73/277 reads (26%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.001); catalogued as COSV52084707, COSV52089735; called by muse, mutect2, varscan2
- INSYN2B | c.764C>T p.S255F | Missense Mutation (SNP) | VAF 68/330 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0.172); catalogued as COSV56976876; called by muse, mutect2, varscan2
- JCAD | c.853C>T p.P285S | Missense Mutation (SNP) | VAF 81/398 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.164); catalogued as rs763764027, COSV64760999; called by muse, mutect2, varscan2
- KIF14 | c.482G>A p.R161K | Missense Mutation (SNP) | VAF 51/259 reads (20%) | SIFT tolerated (0.83); PolyPhen benign (0.01); catalogued as rs1480698249; called by muse, mutect2, varscan2
- KLHL35 | c.1298C>T p.S433L | Missense Mutation (SNP) | VAF 137/492 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs375776972; called by muse, mutect2, varscan2
- KNG1 | c.1396G>A p.E466K | Missense Mutation (SNP) | VAF 94/360 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs746309243, COSV53977273; called by muse, mutect2, varscan2
- MAGEC2 | c.218C>A p.S73Y | Missense Mutation (SNP) | VAF 114/232 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.588); catalogued as rs1255313327, COSV55997858; called by muse, mutect2, varscan2
- MBD5 | c.3652C>T p.H1218Y | Missense Mutation (SNP) | VAF 48/285 reads (17%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.001); catalogued as rs753060251, COSV68698473; ClinVar: likely benign; called by muse, mutect2, varscan2
- MDM4 | c.995C>T p.S332L | Missense Mutation (SNP) | VAF 105/377 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.019); catalogued as rs1169931742; called by muse, mutect2, varscan2
- MYBPC3 | c.1072G>A p.D358N | Missense Mutation (SNP) | VAF 45/233 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.261); catalogued as rs746267533; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NEXMIF | c.1552G>A p.E518K | Missense Mutation (SNP) | VAF 134/265 reads (51%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV50027881; called by muse, mutect2, varscan2
- NPAS4 | c.1478C>T p.S493L | Missense Mutation (SNP) | VAF 75/361 reads (21%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.007); catalogued as rs777170239, COSV60650041; called by muse, mutect2, varscan2
- PCNX2 | c.3442C>T p.R1148C | Missense Mutation (SNP) | VAF 104/380 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768375165, COSV50865368; called by muse, mutect2, varscan2
- PRPF8 | c.4594C>T p.R1532C | Missense Mutation (SNP) | VAF 79/298 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV59267106; called by muse, mutect2, varscan2
- RUVBL2 | c.1292C>T p.S431L | Missense Mutation (SNP) | VAF 84/343 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.006); catalogued as rs1471331743, COSV55487387; called by muse, mutect2, varscan2
- SCN11A | c.1340C>T p.S447F | Missense Mutation (SNP) | VAF 54/199 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV56568787; called by muse, mutect2, varscan2
- SCN7A | c.1042C>T p.R348W | Missense Mutation (SNP) | VAF 81/336 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs867820941, COSV69272216; called by muse, mutect2, varscan2
- SLC26A4 | c.416G>A p.G139E | Missense Mutation (SNP) | VAF 79/195 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM093405, CM981498; called by muse, mutect2, varscan2
- TNN | c.3245G>A p.G1082D | Missense Mutation (SNP) | VAF 88/383 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs201073140; called by muse, mutect2, varscan2
- TTN | c.49570C>T p.R16524C (on ENST00000591111; = p.R9100C on NM_003319.4) | Missense Mutation (SNP) | VAF 95/366 reads (26%) | PolyPhen possibly damaging (0.731); catalogued as rs377575788; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- USH2A | c.4591C>T p.P1531S | Missense Mutation (SNP) | VAF 53/242 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.759); catalogued as COSV56381438; called by muse, mutect2, varscan2
- WNK3 | c.1819G>A p.E607K | Missense Mutation (SNP) | VAF 117/219 reads (53%) | SIFT tolerated (0.13); PolyPhen benign (0.035); catalogued as rs143891385; called by muse, mutect2, varscan2
- ZNF208 | c.2170G>A p.E724K | Missense Mutation (SNP) | VAF 66/345 reads (19%) | SIFT tolerated (0.53); PolyPhen benign (0.365); catalogued as rs878976009; called by muse, mutect2, varscan2
- ZNF528 | c.236C>T p.P79L | Missense Mutation (SNP) | VAF 77/304 reads (25%) | SIFT tolerated (0.74); PolyPhen benign (0.104); catalogued as COSV64621209; called by muse, mutect2, varscan2
- ZNF597 | c.1103C>T p.P368L | Missense Mutation (SNP) | VAF 80/393 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.767); catalogued as rs1220138411; called by muse, mutect2, varscan2
- ZNF711 | c.689C>T p.S230L | Missense Mutation (SNP) | VAF 93/171 reads (54%) | SIFT tolerated (0.22); PolyPhen benign (0.028); catalogued as rs923229140, COSV52155219; called by muse, mutect2, varscan2
- ACTR8 | c.1573_1582del p.D525Kfs*9 | Frame Shift Del (DEL) | VAF 60/236 reads (25%) | called by mutect2, pindel, varscan2
- ADAMTS2 | c.2870A>T p.K957M | Missense Mutation (SNP) | VAF 149/599 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADGRG2 | c.550A>G p.T184A (on ENST00000379869 / NM_001079858.3; = p.T181A on NM_005756.4) | Missense Mutation (SNP) | VAF 59/120 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- ANKRD24 | c.2431G>A p.A811T | Missense Mutation (SNP) | VAF 140/456 reads (31%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.003); called by muse, varscan2
- ANO3 | c.2206C>T p.Q736* | Nonsense Mutation (SNP) | VAF 74/357 reads (21%) | called by muse, mutect2, varscan2
- ARHGEF35 | c.1044T>A p.F348L | Missense Mutation (SNP) | VAF 142/280 reads (51%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATP2B2 | c.2371G>A p.G791S (on ENST00000352432; = p.G757S on NM_001683.5) | Missense Mutation (SNP) | VAF 60/258 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BECN1 | c.1202G>A p.G401D | Missense Mutation (SNP) | VAF 48/208 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- CAMKK2 | c.125C>T p.S42F | Missense Mutation (SNP) | VAF 92/397 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- CD244 | c.554T>A p.L185Q (on ENST00000368033 / NM_001166663.2; = p.L180Q on NM_016382.4) | Missense Mutation (SNP) | VAF 96/353 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- CDK5RAP1 | c.523C>T p.P175S | Missense Mutation (SNP) | VAF 93/339 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- CHSY3 | c.1942C>T p.P648S | Missense Mutation (SNP) | VAF 59/286 reads (21%) | SIFT tolerated (0.39); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CPNE9 | c.1479C>T p.F493= | Splice Region (SNP) | VAF 53/179 reads (30%) | called by muse, mutect2, varscan2
- CSMD2 | c.1849C>T p.H617Y | Missense Mutation (SNP) | VAF 97/445 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- CXCR4 | c.337C>T p.H113Y | Missense Mutation (SNP) | VAF 87/346 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- DDX56 | c.233T>A p.V78E | Missense Mutation (SNP) | VAF 58/237 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FCHO2 | c.1850A>G p.D617G | Missense Mutation (SNP) | VAF 40/179 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- HEPHL1 | c.838C>T p.P280S | Missense Mutation (SNP) | VAF 55/253 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KCNH5 | c.2638G>A p.E880K | Missense Mutation (SNP) | VAF 69/254 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- LCA5L | c.616G>A p.E206K | Missense Mutation (SNP) | VAF 74/266 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MARCHF6 | c.2154G>A p.M718I | Missense Mutation (SNP) | VAF 38/235 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- MARCO | c.1162G>A p.G388R | Missense Mutation (SNP) | VAF 78/329 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MINDY2 | c.631T>G p.L211V | Missense Mutation (SNP) | VAF 58/442 reads (13%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.026); called by mutect2, varscan2
- MMP24 | c.688G>A p.G230S | Missense Mutation (SNP) | VAF 89/376 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MUC2 | c.2902C>T p.P968S | Missense Mutation (SNP) | VAF 93/381 reads (24%) | SIFT tolerated (0.16); called by muse, mutect2, varscan2
- NOX1 | c.751G>A p.D251N | Missense Mutation (SNP) | VAF 82/159 reads (52%) | SIFT tolerated (0.17); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OR1L1 | c.473G>A p.G158E (on ENST00000373686; = p.G108E on NM_001005236.3) | Missense Mutation (SNP) | VAF 69/302 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- OSTN | c.68G>A p.G23E | Missense Mutation (SNP) | VAF 69/256 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- PARP8 | c.779A>G p.K260R | Missense Mutation (SNP) | VAF 38/195 reads (19%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- PCBP4 | c.577C>T p.L193F (on ENST00000322099 / NM_033010.2; = p.L150F on NM_020418.4) | Missense Mutation (SNP) | VAF 54/278 reads (19%) | SIFT tolerated (1); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- PCDHB7 | c.721G>A p.D241N | Missense Mutation (SNP) | VAF 70/336 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- PDZD2 | c.3098C>T p.P1033L | Missense Mutation (SNP) | VAF 94/411 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- PLCD4 | c.302A>G p.N101S | Missense Mutation (SNP) | VAF 112/377 reads (30%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PRDM16 | c.1042G>A p.D348N | Missense Mutation (SNP) | VAF 45/252 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PROKR2 | c.1112G>A p.G371E | Missense Mutation (SNP) | VAF 59/435 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- PRPF19 | c.176A>C p.H59P | Missense Mutation (SNP) | VAF 56/232 reads (24%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRRT3 | c.1356C>A p.N452K | Missense Mutation (SNP) | VAF 112/528 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.667); called by muse, mutect2, varscan2
- RARG | c.927C>G p.D309E | Missense Mutation (SNP) | VAF 114/449 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- RIMBP2 | c.1181C>T p.P394L | Missense Mutation (SNP) | VAF 112/454 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SLC4A8 | c.2599G>A p.G867R | Missense Mutation (SNP) | VAF 99/407 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLFN14 | c.275C>T p.S92L | Missense Mutation (SNP) | VAF 52/219 reads (24%) | SIFT tolerated (0.68); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SNX5 | c.345_347delinsCA p.M116Rfs*9 | Frame Shift Del (DEL) | VAF 41/270 reads (15%) | called by pindel, varscan2*
- SS18 | c.17C>A p.A6E | Missense Mutation (SNP) | VAF 75/328 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.194); called by muse, mutect2, varscan2
- SUPT3H | c.937C>T p.P313S (on ENST00000371460 / NM_181356.3; = p.P302S on NM_003599.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 37/220 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- TAS2R1 | c.371A>G p.K124R | Missense Mutation (SNP) | VAF 66/250 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- TMEM200A | c.461A>T p.E154V | Missense Mutation (SNP) | VAF 72/343 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UBQLN3 | c.1292G>A p.G431E | Missense Mutation (SNP) | VAF 91/393 reads (23%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- WASHC2C | c.2446A>G p.I816V | Missense Mutation (SNP) | VAF 40/207 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ZNF142 | c.5311G>A p.G1771S (on ENST00000411696 / NM_001379660.1; = p.G1571S on NM_001105537.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 97/380 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.151); called by muse, mutect2, varscan2
- ZNF512B | c.383G>C p.R128P | Missense Mutation (SNP) | VAF 23/277 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ZRANB1 | c.1455A>T p.E485D | Missense Mutation (SNP) | VAF 39/205 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- AC068580.4 | c.775C>T p.L259= | Silent (SNP) | VAF 87/343 reads (25%) | called by muse, mutect2, varscan2
- ADRA1D | c.777C>T p.S259= | Silent (SNP) | VAF 115/436 reads (26%) | catalogued as rs745978191; called by muse, mutect2, varscan2
- ADRB2 | c.381C>T p.I127= | Silent (SNP) | VAF 85/340 reads (25%) | catalogued as rs1208893174; called by muse, mutect2, varscan2
- ANKRD66 | c.582C>T p.H194= | Silent (SNP) | VAF 70/362 reads (19%) | catalogued as rs1009574376; called by muse, mutect2, varscan2
- BCL11B | c.1974C>T p.F658= (on ENST00000357195 / NM_001282237.2; = p.F587= on NM_022898.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 35/155 reads (23%) | catalogued as rs1274490272; called by muse, mutect2, varscan2
- C17orf107 | c.432C>T p.A144= | Silent (SNP) | VAF 158/515 reads (31%) | catalogued as rs1179040585; called by muse, mutect2, varscan2
- CD244 | c.553C>T p.L185= (on ENST00000368033 / NM_001166663.2; = p.L180= on NM_016382.4) | Silent (SNP) | VAF 98/353 reads (28%) | catalogued as rs769607978; called by muse, mutect2, varscan2
- CD4 | c.1221C>G p.G407= | Silent (SNP) | VAF 47/261 reads (18%) | called by muse, mutect2, varscan2
- CFAP54 | c.8250T>C p.D2750= | Silent (SNP) | VAF 54/300 reads (18%) | catalogued as COSV100733394; called by muse, mutect2, varscan2
- DCAF1 | c.2343C>T p.F781= | Silent (SNP) | VAF 102/333 reads (31%) | called by muse, mutect2, varscan2
- DNAH3 | c.417G>A p.R139= | Silent (SNP) | VAF 63/297 reads (21%) | catalogued as COSV54525933; called by muse, varscan2
- ETV5 | c.1173T>G p.G391= | Silent (SNP) | VAF 78/326 reads (24%) | called by muse, mutect2, varscan2
- FAM180A | c.201C>T p.I67= | Silent (SNP) | VAF 66/330 reads (20%) | called by muse, mutect2, varscan2
- FANCI | c.940C>T p.L314= | Silent (SNP) | VAF 48/214 reads (22%) | called by mutect2, varscan2
- FBN3 | c.5586G>A p.K1862= | Silent (SNP) | VAF 52/245 reads (21%) | called by muse, mutect2, varscan2
- FOXI3 | c.927C>T p.T309= | Silent (SNP) | VAF 113/418 reads (27%) | catalogued as rs1172359106; called by muse, mutect2, varscan2
- GCFC2 | c.228T>A p.R76= | Silent (SNP) | VAF 89/422 reads (21%) | called by muse, mutect2, varscan2
- GLG1 | c.1863C>T p.I621= | Silent (SNP) | VAF 47/256 reads (18%) | called by muse, mutect2, varscan2
- GOLGA6L7 | c.1785G>A p.Q595= | Silent (SNP) | VAF 65/298 reads (22%) | called by muse, mutect2, varscan2
- HECTD4 | c.7152C>T p.T2384= | Silent (SNP) | VAF 84/339 reads (25%) | called by muse, mutect2, varscan2
- HTR1F | c.732C>T p.S244= | Silent (SNP) | VAF 59/292 reads (20%) | catalogued as COSV60389723, COSV60390174; called by muse, mutect2, varscan2
- INPP5J | c.858G>A p.E286= | Silent (SNP) | VAF 150/527 reads (28%) | called by muse, mutect2, varscan2
- KCNC3 | c.1104C>T p.T368= | Silent (SNP) | VAF 75/401 reads (19%) | catalogued as rs1011930554; called by muse, mutect2, varscan2
- KCNH5 | c.441G>A p.T147= | Silent (SNP) | VAF 48/171 reads (28%) | catalogued as rs753750382, COSV59752889; called by muse, mutect2, varscan2
- KDM4D | c.813C>T p.F271= | Silent (SNP) | VAF 123/475 reads (26%) | called by muse, mutect2, varscan2
- LAMA3 | c.7890G>A p.V2630= (on ENST00000313654 / NM_198129.4; = p.V1021= on NM_000227.6) | Silent (SNP) | VAF 95/360 reads (26%) | called by muse, mutect2, varscan2
- LAMC2 | c.3435G>A p.L1145= | Silent (SNP) | VAF 123/414 reads (30%) | called by muse, mutect2, varscan2
- LPO | c.909C>T p.F303= | Silent (SNP) | VAF 96/406 reads (24%) | called by muse, mutect2, varscan2
- MAPKAPK3 | c.795C>T p.F265= | Silent (SNP) | VAF 68/267 reads (25%) | catalogued as rs765078757; called by muse, mutect2, varscan2
- MMP2 | c.1284C>A p.T428= | Silent (SNP) | VAF 63/277 reads (23%) | called by muse, mutect2, varscan2
- MYH14 | c.2886G>A p.K962= | Silent (SNP) | VAF 68/304 reads (22%) | called by muse, mutect2, varscan2
- MYO18B | c.2514C>T p.A838= | Silent (SNP) | VAF 106/312 reads (34%) | catalogued as rs1368883668; called by muse, mutect2, varscan2
- NPAP1 | c.2352C>T p.T784= | Silent (SNP) | VAF 80/426 reads (19%) | catalogued as rs1420335831, COSV61505105; called by muse, mutect2
- NPC1 | c.516C>T p.A172= | Silent (SNP) | VAF 77/327 reads (24%) | catalogued as rs766387850, COSV52577381; called by muse, mutect2, varscan2
- NXN | c.603C>T p.S201= | Silent (SNP) | VAF 60/259 reads (23%) | catalogued as rs143140734; called by muse, mutect2, varscan2
- PCDHB3 | c.1293G>A p.L431= | Silent (SNP) | VAF 109/360 reads (30%) | catalogued as rs1453280529, COSV99165251; called by muse, mutect2, varscan2
- PDXK | c.938G>A p.*313= | Silent (SNP) | VAF 68/202 reads (34%) | called by muse, mutect2, varscan2
- PLEC | c.3639G>A p.Q1213= (on ENST00000322810 / NM_201380.4; = p.Q1103= on NM_000445.5) | Silent (SNP) | VAF 207/514 reads (40%) | catalogued as rs1554710226; called by muse, mutect2, varscan2
- PNPLA5 | c.1143G>A p.R381= | Silent (SNP) | VAF 98/368 reads (27%) | catalogued as rs772100990; called by muse, mutect2, varscan2
- POU2F3 | c.930G>A p.E310= | Silent (SNP) | VAF 69/249 reads (28%) | catalogued as rs867289322; called by muse, mutect2, varscan2
- PPIE | c.192C>T p.I64= | Silent (SNP) | VAF 73/281 reads (26%) | catalogued as rs138799550; called by muse, mutect2, varscan2
- PPIL2 | c.222G>A p.G74= | Silent (SNP) | VAF 76/281 reads (27%) | called by muse, mutect2, varscan2
- REV3L | c.5949C>T p.S1983= | Silent (SNP) | VAF 111/388 reads (29%) | catalogued as rs773177982; called by muse, mutect2, varscan2
- RGSL1 | c.249C>T p.F83= | Silent (SNP) | VAF 56/232 reads (24%) | called by muse, mutect2, varscan2
- SH2D3C | c.444C>T p.P148= | Silent (SNP) | VAF 73/337 reads (22%) | catalogued as rs766990169; called by muse, mutect2, varscan2
- SLC8A3 | c.39C>T p.F13= | Silent (SNP) | VAF 47/265 reads (18%) | catalogued as COSV100776309; called by muse, mutect2, varscan2
- SOX18 | c.774C>T p.P258= | Silent (SNP) | VAF 128/500 reads (26%) | called by muse, mutect2, varscan2
- SRRT | c.154C>A p.R52= | Silent (SNP) | VAF 78/404 reads (19%) | catalogued as rs1359056291; called by muse, mutect2, varscan2
- STK11IP | c.2346C>T p.R782= | Silent (SNP) | VAF 70/272 reads (26%) | called by muse, mutect2, varscan2
- VIL1 | c.963C>T p.A321= | Silent (SNP) | VAF 41/263 reads (16%) | called by muse, mutect2, varscan2
- WSB2 | c.468G>C p.V156= | Silent (SNP) | VAF 77/272 reads (28%) | called by muse, mutect2, varscan2
- ZFHX2 | c.2379G>A p.R793= | Silent (SNP) | VAF 112/421 reads (27%) | called by muse, mutect2, varscan2
- FAAP24 | c.-106G>A | 5'UTR (SNP) | VAF 59/294 reads (20%) | called by muse, mutect2, varscan2
- GLOD4 | chr17:783202 T>A | 5'Flank (SNP) | VAF 73/291 reads (25%) | called by muse, mutect2, varscan2
- OR8B8 | c.*1G>A | 3'UTR (SNP) | VAF 49/171 reads (29%) | catalogued as COSV100044886; called by muse, mutect2, varscan2
- PSG9 | c.1243+126C>T | Intron (SNP) | VAF 74/262 reads (28%) | catalogued as COSV99392414; called by muse, mutect2, varscan2
- SPNS1 | c.-339G>A | 5'UTR (SNP) | VAF 80/356 reads (22%) | called by muse, mutect2, varscan2
- ZBTB17 | c.-152C>T | 5'UTR (SNP) | VAF 75/408 reads (18%) | catalogued as rs777084258; called by muse, mutect2, varscan2
